Somatic mutation profile of tumor specimen TARGET-10-PAPZRA-09A (aliquot TARGET-10-PAPZRA-09A-01D) from TARGET case TARGET-10-PAPZRA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,448 days).
Specimen TARGET-10-PAPZRA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dc6c9b9-605a-4f5a-8283-338eb564ee38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZRA-10A (Blood Derived Normal), aliquot TARGET-10-PAPZRA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80168b4f-619f-418c-b735-651d9a894167

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 10, Intron 3, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS2 | c.2278G>A p.V760I | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs544243571; called by muse, mutect2, varscan2
- C1QBP | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV56579009; called by muse, mutect2, varscan2
- CDH8 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1349388080; called by muse, mutect2, varscan2
- LPO | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867152504; called by muse, mutect2
- NUDCD3 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs867641636, COSV62647726; called by muse, mutect2
- OPN5 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as rs1370710652, COSV55244312; called by muse, mutect2, varscan2
- PWWP3B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV61800293; called by muse, varscan2
- ZNF479 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100482489, COSV58635651, COSV58636836; called by muse, mutect2, varscan2
- ABCA13 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2
- AK3 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- CAPNS2 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.4); called by mutect2, varscan2
- CDH1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COG5 | c.1865G>C p.R622T (on ENST00000347053 / NM_001379512.1; = p.R643T on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- DLD | c.1524C>A p.N508K | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ETNPPL | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT2 | c.6170G>C p.R2057T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- FRMD7 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- FSIP2 | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.019); called by muse, mutect2
- GGNBP2 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- GLDN | c.1381C>A p.Q461K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- HNRNPH3 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- ILF2 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.163); called by muse, varscan2
- MAP4K4 | c.1837C>A p.P613T (on ENST00000347699 / NM_001242559.2; = p.P582T on NM_145686.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.679); called by muse, varscan2
- MON2 | c.3986C>A p.T1329K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- PKHD1 | c.10395C>G p.I3465M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- REEP3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2
- TMF1 | c.2554G>C p.E852Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC80 | c.2216A>G p.D739G | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF26 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2
- ZNF804B | c.2729C>A p.T910N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- ZNF808 | c.1826C>A p.A609D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.197); called by muse, mutect2
- ARG2 | c.738C>A p.I246= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1436788358, COSV53619126; called by mutect2, varscan2
- EPRS1 | c.2892G>A p.K964= | Silent (SNP) | VAF 39/175 reads (22%) | called by muse, mutect2, varscan2
- HMCN1 | c.3606C>T p.I1202= | Silent (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- KDM4E | c.852C>T p.F284= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs1369767174; called by muse, mutect2, varscan2
- LIAS | c.204C>A p.R68= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99787818; called by mutect2, varscan2
- LRRC4C | c.1545G>A p.G515= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV53430430; called by muse, mutect2, varscan2
- SCNN1G | c.1650C>T p.I550= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs370729372; called by muse, mutect2, varscan2
- SERPINC1 | c.345C>A p.I115= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- TLR4 | c.447C>T p.L149= (on ENST00000355622 / NM_138554.5; = p.L109= on NM_003266.4) | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV62923379; called by muse, mutect2, varscan2
- XKR9 | c.238C>T p.L80= | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- FXYD3 | c.-47C>T | 5'UTR (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-45904C>G | Intron (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- PSG6 | c.706+116C>T | Intron (SNP) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- UQCRB | c.19+38G>T | Intron (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- ZNF513 | c.-12G>C | 5'UTR (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
